Somatic mutation profile of tumor specimen C3N-03441-01 (aliquot CPT0245880006) from CPTAC case C3N-03441, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 67.8 years (24,774 days).
Specimen C3N-03441-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fb18710-27b4-4b6d-b889-8f58d1150e78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03441-31 (Blood Derived Normal), aliquot CPT0245920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/892223c5-deb9-4666-a0cb-b139e51bf47a

The open-access MAF lists 324 somatic variants for this specimen: 229 protein-altering or splice-affecting, 67 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 67, Nonsense Mutation 17, Intron 15, Frame Shift Del 5, 3'Flank 4, RNA 4, Frame Shift Ins 3, Splice Site 3, 5'UTR 3, Splice Region 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 16/179 reads (9%) | catalogued as rs1554893808, CM110124, COSV64297332, COSV64308587, COSV64311451; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 31/297 reads (10%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP6 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV100984224; called by muse, mutect2
- ADCY8 | c.3448C>G p.R1150G | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53910043; called by muse, mutect2, varscan2
- AFP | c.1018A>G p.N340D | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.339); catalogued as rs1161405762; called by muse, mutect2, varscan2
- AKAP6 | c.4468G>C p.E1490Q | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV55212497; called by muse, mutect2, varscan2
- ANKS1B | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269579871, COSV61345301; called by muse, mutect2, varscan2
- ARHGAP11B | c.648C>G p.N216K | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as COSV101451892; called by muse, mutect2, varscan2
- ARHGAP18 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371036479, COSV100936448; called by muse, mutect2
- ARHGEF6 | c.1234A>G p.K412E | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV99166464; called by muse, mutect2
- ATCAY | c.914T>A p.L305Q | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100008375; called by muse, mutect2
- ATP8A2 | c.1975C>G p.R659G | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV54950475; called by muse, mutect2, varscan2
- BPHL | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as rs756405772, COSV66744512; called by muse, mutect2
- C10orf71 | c.2194T>A p.S732T | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60503916; called by muse, mutect2
- C5orf52 | c.378A>T p.K126N | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as COSV69626363; called by muse, mutect2
- CCDC185 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs1175836598; called by muse, mutect2, varscan2
- CD93 | c.94G>T p.V32L | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV55663676; called by muse, mutect2, varscan2
- CFAP69 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as rs572240323, COSV60188980; called by muse, mutect2
- CHFR | c.1888A>G p.T630A (on ENST00000432561 / NM_001161345.1; = p.T589A on NM_018223.2) | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1425682767; called by muse, mutect2
- CIT | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770757019, COSV55865386, COSV55886953; called by muse, mutect2
- CNTNAP4 | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV56668810; called by muse, mutect2, varscan2
- COL11A1 | c.4142G>A p.G1381E | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62200717, COSV62202647; called by muse, mutect2
- CTSH | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV54984418; called by muse, mutect2
- CYP11B1 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 92/857 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM156820, COSV99455177; called by muse, mutect2
- CYP11B1 | c.167G>C p.W56S | Missense Mutation (SNP) | VAF 91/856 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs778994889; called by muse, mutect2
- DCX | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100576547; called by muse, mutect2, varscan2
- DLK1 | c.528dup p.N177Qfs*11 | Frame Shift Ins (INS) | VAF 36/266 reads (14%) | catalogued as rs1331816882; called by mutect2, pindel, varscan2
- DST | c.22130A>G p.K7377R (on ENST00000361203 / NM_001374722.1; = p.K5087R on NM_015548.5) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as rs1168581623; called by muse, varscan2
- DTX2 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56859799; called by muse, mutect2
- EOMES | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV55410882; called by muse, mutect2, varscan2
- F2RL3 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs914269296; called by muse, mutect2
- FAM135B | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as rs1458780221, COSV52726793; called by muse, mutect2
- FAT4 | c.13855A>G p.I4619V | Missense Mutation (SNP) | VAF 62/343 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV99060178; called by muse, mutect2, varscan2
- FN3KRP | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs182510567; called by muse, mutect2
- GPR135 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1442789262; called by muse, mutect2
- HOXD3 | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.374); catalogued as rs772793891, COSV50885305; called by muse, mutect2, varscan2
- HTR1B | c.383C>A p.S128* | Nonsense Mutation (SNP) | VAF 9/216 reads (4%) | catalogued as COSV64051714; called by muse, mutect2
- ITPKB | c.2689G>A p.D897N | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900260287; called by muse, mutect2, varscan2
- KLK12 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51577893; called by muse, mutect2, varscan2
- KRTAP15-1 | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV61878125; called by muse, mutect2
- LPAR4 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472738201, COSV70912902; called by muse, mutect2, varscan2
- LPCAT1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1216469134; called by muse, mutect2
- MDP1 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as COSV99164576, COSV99164584; called by muse, mutect2
- MYH9 | c.4982G>A p.R1661H | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs773424441, COSV53386173, COSV53390631; called by muse, mutect2
- NCF2 | c.1174C>A p.L392M | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62314900; called by muse, mutect2
- NOG | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 36/114 reads (32%) | catalogued as COSV60447694; called by muse, mutect2, varscan2
- NSD3 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV57622406; called by muse, mutect2
- OR2M2 | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV100677226; called by muse, mutect2, varscan2
- OR2T1 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs145124094, COSV100822279; called by muse, mutect2, varscan2
- PALB2 | c.2641G>A p.G881S | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs766315705, COSV99849015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2G1B | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs5635; called by muse, mutect2
- PLCB3 | c.3542C>T p.A1181V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs776004312, COSV99657659; called by muse, mutect2, varscan2
- PLCL1 | c.2873G>T p.G958V | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.801); catalogued as COSV99071927; called by muse, mutect2, varscan2
- PPP2R5C | c.1478C>A p.A493E | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.048); catalogued as rs1401087302; called by muse, mutect2, varscan2
- PRDM9 | c.1505A>T p.Q502L | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV57010015; called by muse, mutect2, varscan2
- PREPL | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.095); catalogued as rs373786632; called by muse, mutect2
- PSD2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 64/481 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV51197695; called by muse, mutect2, varscan2
- PUS3 | c.596dup p.R201Sfs*3 | Frame Shift Ins (INS) | VAF 22/174 reads (13%) | catalogued as rs1171176058; called by mutect2, pindel, varscan2
- RAB5A | c.30C>G p.N10K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV56086215; called by muse, mutect2
- RCC1L | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 27/456 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs1248094330; called by muse, mutect2
- RNF215 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1398288459; called by muse, mutect2
- RTKN | c.896G>A p.R299H (on ENST00000272430 / NM_001015055.2; = p.R286H on NM_033046.2) | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376959473, COSV99269632; called by muse, mutect2, varscan2
- RYR1 | c.2203C>A p.H735N | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1510297; called by muse, mutect2, varscan2
- RYR2 | c.1088T>C p.I363T | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs1360751290; called by muse, mutect2
- SEPHS1 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs1258469101, COSV59257147; called by muse, mutect2
- SFMBT2 | c.1313T>C p.M438T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs1323415931; called by muse, varscan2
- SHROOM4 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455083919; called by muse, mutect2, varscan2
- SIGLEC11 | c.1361A>G p.H454R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs760450249; called by mutect2, varscan2
- SIPA1L3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.083); catalogued as rs753429177, COSV55917980; called by muse, mutect2, varscan2
- SPTLC2 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1011016523, COSV53640470; called by muse, mutect2, varscan2
- SRRM5 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1402783305; called by muse, mutect2, varscan2
- SWAP70 | c.306C>A p.N102K | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV100013480; called by muse, mutect2, varscan2
- TBX6 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 51/212 reads (24%) | catalogued as COSV99661678; called by muse, mutect2, varscan2
- TNRC18 | c.7770del p.N2590Kfs*211 | Frame Shift Del (DEL) | VAF 24/217 reads (11%) | catalogued as COSV60306660; called by mutect2, pindel, varscan2
- TOX | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs763676335; called by muse, mutect2, varscan2
- TP53 | c.358A>C p.K120Q | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912658, CM921039, COSV52676498, COSV52692352, COSV53551619, COSV53685479; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPBG | c.1186A>C p.M396L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV100869792, COSV63882759; called by muse, mutect2, varscan2
- TTN | c.86500G>A p.D28834N (on ENST00000591111; = p.D21410N on NM_003319.4) | Missense Mutation (SNP) | VAF 48/464 reads (10%) | PolyPhen probably damaging (0.998); catalogued as COSV60392139; called by muse, mutect2, varscan2
- TTN | c.63923A>G p.D21308G (on ENST00000591111; = p.D13884G on NM_003319.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | PolyPhen possibly damaging (0.783); catalogued as rs1559471693; called by muse, mutect2, varscan2
- WDHD1 | c.2144A>G p.Y715C | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs762281286; called by muse, mutect2, varscan2
- WDPCP | c.1474A>G p.I492V | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.289); catalogued as rs1558548737; called by muse, mutect2
- XPO5 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs867889729, COSV99541465; called by muse, mutect2
- ZBED9 | c.1400G>T p.C467F | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); catalogued as COSV71729760; called by muse, mutect2, varscan2
- ZEB2 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 15/385 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57964996; called by muse, mutect2
- ZNF160 | c.1850G>T p.G617V | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306564731; called by muse, mutect2, varscan2
- ZNF768 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs376086328; called by muse, mutect2
- A4GNT | c.804G>C p.W268C | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACTR5 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2
- ADAD1 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM2 | c.1504A>T p.K502* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- AFG3L2 | c.561A>T p.R187S | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- AL035460.1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.342); called by muse, mutect2
- APC2 | c.5994C>G p.I1998M | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ARGLU1 | c.573+6G>A | Splice Region (SNP) | VAF 14/293 reads (5%) | called by muse, mutect2
- ARSB | c.1183A>G p.I395V | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ATP1B1 | c.81G>T p.R27S | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- AXDND1 | c.2921C>A p.S974Y | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); called by muse, mutect2
- BLM | c.3789T>G p.I1263M | Missense Mutation (SNP) | VAF 26/335 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- BMPER | c.1412T>C p.L471S | Missense Mutation (SNP) | VAF 24/285 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- C1QTNF2 | c.572G>A p.G191D (on ENST00000393975; = p.G146D on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- C1orf94 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2
- CACNG5 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCDC58 | c.217A>G p.N73D | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CHMP7 | c.1087C>G p.Q363E | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2
- CLEC7A | c.107C>G p.S36W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CLK1 | c.1256G>A p.W419* | Nonsense Mutation (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- CNTN6 | c.382A>C p.T128P | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL22A1 | c.2863G>A p.G955S | Missense Mutation (SNP) | VAF 23/405 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPM | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CSMD3 | c.7027C>A p.P2343T (on ENST00000297405 / NM_001363185.1; = p.P2239T on NM_052900.3) | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYP4X1 | c.511T>C p.C171R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- DAPK1 | c.1777G>T p.V593L | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCHS1 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCHS1 | c.1144G>T p.G382* | Nonsense Mutation (SNP) | VAF 20/207 reads (10%) | called by muse, mutect2
- DCST1 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.193); called by muse, mutect2
- DEFB113 | c.59-2A>T p.X20_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- DNALI1 | c.141C>A p.S47R (on ENST00000296218; = p.S25R on NM_003462.5) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.476); called by muse, mutect2
- DOCK3 | c.1055A>C p.E352A | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- DOCK8 | c.5523T>G p.F1841L | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- DPYSL3 | c.313+2T>G p.X105_splice | Splice Site (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- DSCAM | c.5014A>G p.R1672G | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2
- EMC3 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 13/172 reads (8%) | called by muse, mutect2
- EVX2 | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAHD2A | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 29/196 reads (15%) | called by muse, mutect2, varscan2
- FAT1 | c.12786T>A p.S4262R | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2
- FBRS | c.1131C>G p.F377L (on ENST00000287468; = p.F897L on NM_001105079.3) | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FOXA2 | c.544C>G p.L182V (on ENST00000377115 / NM_153675.3; = p.L188V on NM_021784.5) | Missense Mutation (SNP) | VAF 48/441 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FREM3 | c.1345A>G p.R449G | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- GCN1 | c.1795A>G p.K599E | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2
- GLMN | c.441G>T p.L147F | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLYCTK | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, mutect2
- GPR158 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- GRIN2B | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 37/345 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GSDMC | c.1092G>T p.L364F | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2
- H2AC6 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); called by muse, mutect2
- HEATR5B | c.389T>C p.L130S | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- HSP90AA1 | c.361G>C p.A121P | Missense Mutation (SNP) | VAF 11/390 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- IDO1 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2
- IFFO2 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ISL1 | c.933+1G>T p.X311_splice | Splice Site (SNP) | VAF 52/341 reads (15%) | called by muse, mutect2, varscan2
- JMY | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- KCNS2 | c.1279A>G p.M427V | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDR | c.3080G>T p.R1027M | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA1109 | c.9436G>C p.D3146H | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2
- KIAA1549 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 21/343 reads (6%) | called by muse, mutect2
- KIF7 | c.1702del p.L568Wfs*31 | Frame Shift Del (DEL) | VAF 45/387 reads (12%) | called by mutect2, pindel, varscan2
- KMT5C | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- LETM1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LINC01118 | n.1243G>A | Splice Region (SNP) | VAF 36/230 reads (16%) | called by muse, mutect2, varscan2
- LRIT2 | c.161C>G p.S54C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- LRP1B | c.12055A>T p.T4019S | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.192); called by muse, mutect2
- LRP6 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 44/227 reads (19%) | called by muse, mutect2, varscan2
- LRRC10B | c.841T>C p.F281L | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MALRD1 | c.4835T>C p.I1612T | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2
- MAPT | c.2314G>A p.E772K (on ENST00000262410 / NM_001377265.1; = p.E380K on NM_005910.5) | Missense Mutation (SNP) | VAF 20/405 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MARK1 | c.42C>A p.D14E | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- ME2 | c.745A>T p.N249Y | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MMEL1 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH2B | c.3511A>C p.S1171R | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MROH5 | c.3745T>C p.C1249R | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MS4A3 | c.645A>T p.*215Yext*6 | Nonstop Mutation (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- MUC16 | c.8036G>A p.G2679D | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); called by muse, mutect2
- MUC16 | c.5030T>C p.M1677T | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH4 | c.4793T>C p.V1598A | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- MYH7 | c.5332del p.H1778Tfs*5 | Frame Shift Del (DEL) | VAF 51/531 reads (10%) | called by mutect2, pindel, varscan2
- MYLK | c.3730C>T p.P1244S | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYO7B | c.3336C>G p.C1112W | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDUFA10 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 27/373 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2
- NLRP7 | c.730C>A p.Q244K | Missense Mutation (SNP) | VAF 11/280 reads (4%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.871); called by muse, mutect2
- NPBWR2 | c.544T>A p.F182I | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OBSCN | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 51/420 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2C3 | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 20/309 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- OR2K2 | c.789C>G p.N263K (on ENST00000374428; = p.N234K on NM_205859.2) | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- OR4N5 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR5J2 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PALB2 | c.2642G>T p.G881V | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PAX4 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 68/480 reads (14%) | called by muse, mutect2, varscan2
- PEX1 | c.2741A>T p.Y914F | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- PKN3 | c.1427G>C p.G476A | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- PPHLN1 | c.253A>G p.R85G | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2
- PRRC2A | c.2686C>A p.P896T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRSS16 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- PSMC5 | c.436T>C p.S146P | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PTAFR | c.547C>G p.P183A | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- RAG1 | c.2939G>T p.R980M | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RELN | c.9689C>A p.A3230D | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2
- RFPL4AL1 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 50/832 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- RP1 | c.3120A>G p.I1040M | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.288); called by muse, mutect2
- SEPSECS | c.1056A>G p.I352M | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- SEPTIN9 | c.1499T>A p.V500E (on ENST00000427177 / NM_001113491.2; = p.V482E on NM_006640.4) | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SESN2 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- SLC4A7 | c.2488A>G p.I830V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2
- SLC9A1 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- SNAP47 | c.738T>G p.C246W | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- SOX30 | c.606A>C p.K202N | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); called by muse, mutect2
- SPATA16 | c.1672dup p.T558Nfs*41 | Frame Shift Ins (INS) | VAF 35/289 reads (12%) | called by mutect2, pindel, varscan2
- SPATS2L | c.327_343del p.N109Kfs*8 | Frame Shift Del (DEL) | VAF 54/508 reads (11%) | called by mutect2, pindel
- SRRT | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- STAB2 | c.2486C>A p.A829D | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2
- STAP2 | c.1175A>T p.Q392L (on ENST00000594605 / NM_001013841.2; = p.Q438L on NM_017720.3) | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- STX2 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- STYXL2 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SUN1 | c.824C>A p.S275Y (on ENST00000405266 / NM_001367651.1; = p.S238Y on NM_001130965.3 and 17 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SYNE1 | c.18626G>T p.S6209I (on ENST00000367255 / NM_182961.4; = p.S6138I on NM_033071.3) | Missense Mutation (SNP) | VAF 28/654 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYTL2 | c.2167A>T p.T723S (on ENST00000528231 / NM_001162951.2; = p.T699S on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- TEDC2 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- TERT | c.2714T>A p.V905E | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THADA | c.3212T>C p.L1071P | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TINAG | c.422C>A p.T141K | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.057); called by muse, mutect2
- TMCC3 | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TOPBP1 | c.576G>C p.M192I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- TOX | c.524C>A p.P175Q | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOX2 | c.1372A>G p.S458G (on ENST00000358131 / NM_001098798.2; = p.S434G on NM_032883.3) | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRAM1L1 | c.629_630delinsG p.A210Gfs*6 | Frame Shift Del (DEL) | VAF 34/217 reads (16%) | called by pindel, varscan2*
- TRAV8-3 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- TRPA1 | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTBK2 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- TTC21B | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- TTC7B | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- VGLL4 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZDHHC23 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFC3H1 | c.3878G>A p.W1293* | Nonsense Mutation (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- ZFP82 | c.394A>G p.R132G | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF469 | c.5916G>C p.Q1972H (on ENST00000437464; = p.Q2000H on NM_001367624.2) | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.049); called by muse, mutect2
- ZNF471 | c.632G>T p.C211F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF485 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF687 | c.1778A>T p.Q593L | Missense Mutation (SNP) | VAF 56/433 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF91 | c.3263G>T p.S1088I | Missense Mutation (SNP) | VAF 15/310 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.306); called by muse, mutect2
- ZNF91 | c.3262A>C p.S1088R | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ABCA2 | c.2124C>T p.H708= (on ENST00000614293; = p.H678= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/206 reads (17%) | catalogued as rs761956645; called by muse, mutect2, varscan2
- ACE2 | c.1221C>A p.I407= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as rs1459623504, COSV99382845; called by muse, mutect2, varscan2
- ADD2 | c.546G>A p.A182= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as rs150383515; called by muse, mutect2
- ANKRD30B | c.693C>T p.V231= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV62824600; called by muse, mutect2
- ARSD | c.681G>A p.A227= | Silent (SNP) | VAF 17/211 reads (8%) | called by muse, mutect2
- ATP8B1 | c.3474A>G p.L1158= | Silent (SNP) | VAF 19/420 reads (5%) | called by muse, mutect2
- ATP8B3 | c.1671G>C p.G557= | Silent (SNP) | VAF 70/355 reads (20%) | called by muse, mutect2, varscan2
- BAZ1A | c.3447G>T p.A1149= | Silent (SNP) | VAF 27/366 reads (7%) | catalogued as COSV100701088, COSV100701208; called by muse, mutect2
- C1orf116 | c.216C>T p.D72= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as rs565510495, COSV63943698, COSV63943726; called by muse, mutect2, varscan2
- CACNA1S | c.207C>A p.A69= | Silent (SNP) | VAF 73/559 reads (13%) | called by muse, mutect2, varscan2
- COL8A1 | c.192C>A p.A64= | Silent (SNP) | VAF 37/303 reads (12%) | called by muse, mutect2, varscan2
- CRYGA | c.72C>A p.P24= | Silent (SNP) | VAF 32/486 reads (7%) | called by muse, mutect2
- CSNK2A1 | c.801A>G p.P267= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as rs1469499409; called by muse, mutect2, varscan2
- CYBRD1 | c.309C>A p.A103= | Silent (SNP) | VAF 39/403 reads (10%) | catalogued as rs141691061; called by muse, mutect2
- DRP2 | c.213T>C p.S71= | Silent (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- EIF4G3 | c.3648A>G p.A1216= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- EPB41L2 | c.2739C>T p.G913= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs202080247, COSV61356373; called by muse, mutect2, varscan2
- FAHD2A | c.480G>T p.V160= | Silent (SNP) | VAF 28/194 reads (14%) | catalogued as rs761473289; called by muse, mutect2, varscan2
- FAM71B | c.1689G>A p.K563= | Silent (SNP) | VAF 14/388 reads (4%) | catalogued as COSV57230494; called by muse, mutect2
- FCGBP | c.7161G>T p.V2387= | Silent (SNP) | VAF 39/1020 reads (4%) | called by muse, mutect2
- FKBP11 | c.504C>T p.L168= | Silent (SNP) | VAF 22/244 reads (9%) | called by muse, mutect2
- FYB1 | c.837T>G p.G279= | Silent (SNP) | VAF 15/406 reads (4%) | called by muse, mutect2
- GOLGA3 | c.2997C>T p.Y999= | Silent (SNP) | VAF 32/390 reads (8%) | catalogued as rs373159506; called by muse, mutect2
- GOLGA8T | c.1209G>T p.L403= | Silent (SNP) | VAF 30/566 reads (5%) | called by muse, mutect2
- GRID2 | c.1749G>T p.L583= | Silent (SNP) | VAF 28/400 reads (7%) | catalogued as COSV99940814; called by muse, mutect2
- HEATR5A | c.885G>A p.L295= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs1465404831; called by muse, mutect2
- HTR3A | c.228G>A p.K76= | Silent (SNP) | VAF 28/357 reads (8%) | catalogued as COSV100248555; called by muse, mutect2
- IGSF1 | c.3558C>G p.P1186= | Silent (SNP) | VAF 15/176 reads (9%) | catalogued as rs773045436, COSV63837602; called by muse, mutect2
- LACTBL1 | c.585C>A p.A195= (on ENST00000618559; = p.A240= on NM_001289974.2) | Silent (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
- LIMK2 | c.234G>T p.L78= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- LRP2 | c.8724T>A p.A2908= | Silent (SNP) | VAF 57/466 reads (12%) | called by muse, mutect2, varscan2
- MUC22 | c.4815A>G p.A1605= | Silent (SNP) | VAF 16/315 reads (5%) | called by muse, mutect2
- MUC4 | c.270C>A p.T90= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as rs756592872, COSV62185264; called by muse, mutect2
- MYBPC1 | c.2085T>C p.F695= (on ENST00000550270 / NM_206820.2; = p.F720= on NM_002465.4) | Silent (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- MYO7B | c.3819C>T p.G1273= | Silent (SNP) | VAF 19/342 reads (6%) | catalogued as rs548314152; called by muse, mutect2
- NES | c.4752G>A p.G1584= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs141247172; called by muse, mutect2
- NFKBIZ | c.573T>C p.P191= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV58200677; called by muse, mutect2, varscan2
- NIBAN2 | c.153G>A p.T51= | Silent (SNP) | VAF 46/217 reads (21%) | catalogued as rs756182942; called by muse, mutect2, varscan2
- NRF1 | c.930T>C p.F310= | Silent (SNP) | VAF 34/227 reads (15%) | called by muse, mutect2, varscan2
- NUP98 | c.294G>T p.G98= | Silent (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- NXN | c.732A>G p.K244= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- OR2A14 | c.465T>G p.A155= | Silent (SNP) | VAF 41/399 reads (10%) | called by muse, mutect2, varscan2
- OR2T1 | c.411C>A p.R137= | Silent (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- OR2T1 | c.412C>A p.R138= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as rs140525966; called by muse, mutect2
- OR4A16 | c.108A>G p.T36= | Silent (SNP) | VAF 11/220 reads (5%) | catalogued as rs1441630173; called by muse, mutect2
- OR8B8 | c.921A>G p.K307= | Silent (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- PDE10A | c.2331C>T p.S777= | Silent (SNP) | VAF 19/225 reads (8%) | catalogued as rs778165952; called by muse, mutect2
- PTAFR | c.546G>T p.V182= | Silent (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2
- PTEN | c.126T>C p.L42= | Silent (SNP) | VAF 16/179 reads (9%) | called by muse, mutect2
- RAD17 | c.1098G>A p.L366= (on ENST00000380774 / NM_133339.2; = p.L355= on NM_002873.1) | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- REG3A | c.147C>G p.S49= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as COSV100532629; called by muse, mutect2, varscan2
- RYR1 | c.13518C>T p.A4506= | Silent (SNP) | VAF 24/348 reads (7%) | catalogued as rs749640716; ClinVar: likely benign; called by muse, mutect2
- SIPA1L3 | c.600C>T p.R200= | Silent (SNP) | VAF 15/251 reads (6%) | catalogued as rs766428011; called by muse, mutect2
- SLC6A5 | c.1089C>G p.A363= | Silent (SNP) | VAF 22/400 reads (6%) | called by muse, mutect2
- SPATA31D1 | c.2106G>T p.L702= | Silent (SNP) | VAF 38/662 reads (6%) | called by muse, mutect2
- SPATA5L1 | c.615T>C p.L205= | Silent (SNP) | VAF 23/377 reads (6%) | called by muse, mutect2
- SPATA6 | c.825T>C p.S275= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- SPN | c.48C>T p.D16= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs556201400, COSV64071150; called by muse, varscan2
- SRCIN1 | c.867C>T p.I289= (on ENST00000621492; = p.I255= on NM_025248.3) | Silent (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2, varscan2
- STOX1 | c.927G>A p.K309= | Silent (SNP) | VAF 75/424 reads (18%) | called by muse, mutect2, varscan2
- TCP1 | c.480C>A p.I160= | Silent (SNP) | VAF 13/154 reads (8%) | called by muse, mutect2
- USH2A | c.15000C>T p.D5000= | Silent (SNP) | VAF 54/316 reads (17%) | catalogued as rs756699087, COSV56351375; called by muse, mutect2, varscan2
- WNK2 | c.3465C>T p.G1155= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as rs145609783; called by muse, mutect2
- ZBBX | c.258A>G p.K86= | Silent (SNP) | VAF 26/283 reads (9%) | called by muse, mutect2
- ZIK1 | c.1263C>T p.I421= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- ZNF821 | c.705G>T p.L235= (on ENST00000425432 / NM_001376297.1; = p.L193= on NM_017530.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 53/373 reads (14%) | catalogued as rs1478086569, COSV57987543; called by muse, mutect2, varscan2
- ZSWIM9 | c.600G>A p.V200= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- ADAM1A | n.1268T>C | RNA (SNP) | VAF 29/246 reads (12%) | called by muse, mutect2, varscan2
- AGMO | c.1263+58973G>T | Intron (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- AL133467.5 | chr14:95662613 A>T | 3'Flank (SNP) | VAF 27/210 reads (13%) | called by muse, mutect2, varscan2
- ARID5B | c.734-1419T>C | Intron (SNP) | VAF 22/186 reads (12%) | called by muse, varscan2
- ARMCX4 | c.1038+1024C>A | Intron (SNP) | VAF 10/90 reads (11%) | catalogued as rs1556008376; called by mutect2, varscan2
- ASCC1 | chr10:72096263 C>T | 3'Flank (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- C5orf60 | n.820C>T | RNA (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- CACNG7 | c.-6C>T | 5'UTR (SNP) | VAF 75/320 reads (23%) | catalogued as rs1399903345; called by muse, mutect2, varscan2
- FUNDC2P2 | n.346T>A | RNA (SNP) | VAF 54/461 reads (12%) | called by muse, mutect2, varscan2
- GNAS | c.659+33G>A | Intron (SNP) | VAF 27/512 reads (5%) | catalogued as rs1230646893; called by muse, mutect2
- GSDMC | c.916+15G>A | Intron (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- GUSBP3 | chr5:69635377 T>C | 3'Flank (SNP) | VAF 20/112 reads (18%) | called by mutect2, varscan2
- HOXA10 | c.*858A>T | 3'UTR (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- ICOSLG | c.898+319C>A | Intron (SNP) | VAF 8/78 reads (10%) | catalogued as COSV60266639; called by mutect2, varscan2
- IMPA2 | c.231-1505G>C | Intron (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2, varscan2
- ITGB2 | c.1155+23C>T | Intron (SNP) | VAF 28/315 reads (9%) | called by muse, mutect2
- LINC01556 | n.85del | RNA (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- MASP1 | c.1303+5706G>C | Intron (SNP) | VAF 63/687 reads (9%) | called by muse, mutect2
- MED16 | c.2098+311C>T | Intron (SNP) | VAF 14/260 reads (5%) | catalogued as rs752444603; called by muse, mutect2
- MOCS1 | c.124-34G>T | Intron (SNP) | VAF 39/574 reads (7%) | called by muse, mutect2
- NR1I2 | c.-23+529T>C | Intron (SNP) | VAF 78/454 reads (17%) | catalogued as COSV61977389; called by muse, mutect2, varscan2
- PTTG1IP | c.*16C>A | 3'UTR (SNP) | VAF 24/252 reads (10%) | called by muse, mutect2
- SYT14 | chr1:210163954 C>T | 3'Flank (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+51G>T | Intron (SNP) | VAF 7/57 reads (12%) | catalogued as rs1359295131; called by muse, mutect2, varscan2
- TMTC1 | c.939-26596C>T | Intron (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2
- TSPO2 | c.-62C>A | 5'UTR (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- ZDHHC23 | c.1217-42T>A | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- ZNF280C | c.-11C>T | 5'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
